Somatic mutation profile of tumor specimen TCGA-DK-A2I4-01A (aliquot TCGA-DK-A2I4-01A-11D-A21A-08) from TCGA case TCGA-DK-A2I4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DK-A2I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29957c02-7e8d-4165-90c0-2a380e3870a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A2I4-10A (Blood Derived Normal), aliquot TCGA-DK-A2I4-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8923acfe-51a2-427e-ba40-42cac87ee9ea

The open-access MAF lists 996 somatic variants for this specimen: 680 protein-altering or splice-affecting, 298 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 587, Silent 298, Nonsense Mutation 71, Splice Site 12, Intron 7, RNA 6, Splice Region 5, 3'Flank 2, Translation Start Site 2, Frame Shift Ins 2, 5'UTR 2, Frame Shift Del 1.

Variants (750 of 996; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- CAMK2B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554386687, COSV51661795, COSV51663139; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STXBP1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as rs1057519501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7590G>C p.K2530N | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV71288296, COSV71289777; called by muse, mutect2, varscan2
- ABCA4 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as CM161622, COSV64673228, COSV64674391; called by muse, varscan2
- ABRAXAS2 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1564927134, COSV53717353; called by muse, mutect2, varscan2
- AC092143.1 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100205964, COSV59248030; called by muse, mutect2, varscan2
- ACACA | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs774611562; called by muse, mutect2, varscan2
- ACAP2 | c.574A>T p.M192L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV58752684; called by muse, mutect2
- ACE | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761401927, COSV52008290, COSV99326963, COSV99327897; called by muse, mutect2, varscan2
- ACE2 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 9/95 reads (9%) | catalogued as rs868599322, COSV99382874; called by muse, mutect2, varscan2
- ACTG1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as COSV59509957, COSV59511807; called by muse, mutect2, varscan2
- ADAMTS18 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as rs1276942011, COSV51417502; called by muse, mutect2
- ADGRF5 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769133119, COSV51935349, COSV99346140; called by muse, mutect2, varscan2
- ADGRG1 | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1367306359, COSV65635780; called by muse, mutect2, varscan2
- ADH1A | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV99265926; called by muse, mutect2, varscan2
- ADPRM | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV65754763; called by muse, mutect2, varscan2
- AFF2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.224); catalogued as COSV53993496; called by muse, mutect2, varscan2
- AHNAK2 | c.15794C>T p.S5265F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV60914656, COSV60918416; called by muse, mutect2, varscan2
- AKAP9 | c.1969G>C p.D657H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV62348968; called by muse, mutect2
- AKAP9 | c.9466C>G p.Q3156E (on ENST00000359028; = p.Q3132E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV62348985; called by muse, mutect2
- AL031777.2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV61912045, COSV61912079; called by muse, mutect2, varscan2
- ALMS1 | c.10552C>T p.H3518Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52512259; called by muse, mutect2, varscan2
- ALPK2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64490346, COSV64493905; called by muse, mutect2, varscan2
- AMDHD2 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.943); catalogued as COSV53550826, COSV53551133; called by muse, mutect2
- AMPD3 | c.238A>G p.M80V (on ENST00000396553 / NM_001025389.2; = p.M89V on NM_000480.3) | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs766977576, COSV67331315; called by muse, mutect2, varscan2
- ANAPC4 | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59544638; called by muse, mutect2
- ANGPT4 | c.1452C>A p.F484L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV67921889; called by muse, mutect2
- ANGPTL4 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 78/693 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56844959; called by muse, mutect2, varscan2
- ANK3 | c.7354G>C p.E2452Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs1163747953, COSV55062895; called by muse, mutect2, varscan2
- ANKIB1 | c.2935G>C p.D979H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV56062790; called by muse, mutect2, varscan2
- ANKRD17 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58222378; called by muse, mutect2
- APC | c.3466G>T p.E1156* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as CM095525, COSV57324823; called by muse, mutect2
- APOL1 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV59869229; called by muse, mutect2, varscan2
- APOL2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 35/291 reads (12%) | catalogued as COSV99969157; called by muse, mutect2, varscan2
- APOL2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50772291, COSV50773384; called by muse, mutect2, varscan2
- AQP8 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 33/304 reads (11%) | catalogued as COSV54844479; called by muse, mutect2, varscan2
- ARFGEF2 | c.4774G>C p.D1592H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV64212918; called by muse, mutect2
- ARHGAP28 | c.1952C>G p.S651C (on ENST00000383472 / NM_001366230.1; = p.S492C on NM_001010000.3) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51639796; called by muse, mutect2, varscan2
- ARHGEF18 | c.1591G>A p.D531N (on ENST00000359920 / NM_001130955.2; = p.D427N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60470721; called by muse, mutect2, varscan2
- ARHGEF25 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as COSV54087346; called by muse, varscan2
- ARID4B | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV51605176; called by muse, mutect2, varscan2
- ARMC3 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372574174; called by muse, mutect2
- ARMC5 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs539440145, COSV51657250; called by muse, mutect2, varscan2
- ARNTL2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV53826413; called by muse, mutect2, varscan2
- ASTN1 | c.3706C>T p.L1236F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV62494766; called by muse, mutect2
- ASXL1 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV60105371, COSV60110393; called by muse, mutect2
- ATF7IP2 | c.1952G>A p.R651K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777979474, COSV61093948; called by muse, mutect2, varscan2
- ATP13A3 | c.3204A>G p.I1068M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1166408330, COSV55465605; called by muse, mutect2
- ATP13A4 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV61321197; called by muse, mutect2, varscan2
- AVPR1B | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 133/781 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV65638236; called by muse, mutect2, varscan2
- B3GNT9 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV54627689; called by muse, mutect2, varscan2
- BAZ2B | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58603117; called by muse, mutect2, varscan2
- BBS9 | c.1538-1G>C p.X513_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV54172298; called by muse, mutect2, varscan2
- BCL2L13 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV58226269; called by muse, mutect2
- BDP1 | c.7848C>G p.I2616M | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755935161, COSV62432104; called by muse, mutect2
- BNIPL | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV54847381; called by muse, varscan2
- BPTF | c.6509G>A p.G2170E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV58839380; called by muse, mutect2, varscan2
- BRD2 | c.1272C>G p.N424K | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66373655; called by muse, mutect2, varscan2
- BTBD7 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58287327; called by muse, mutect2, varscan2
- BTN3A1 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50024934; called by muse, mutect2, varscan2
- BTN3A1 | c.992-1G>A p.X331_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as COSV50024942; called by muse, mutect2, varscan2
- BUB1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV57064433; called by muse, mutect2
- C1QTNF12 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as rs1557535506, COSV57802813; called by muse, mutect2, varscan2
- CADM2 | c.664G>C p.E222Q (on ENST00000407528 / NM_001167674.2; = p.E224Q on NM_153184.4) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.957); catalogued as COSV67381454; called by muse, mutect2, varscan2
- CALCR | c.1307G>A p.R436H (on ENST00000649521 / NM_001164737.2; = p.R420H on NM_001742.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64006033; called by muse, mutect2, varscan2
- CAMK2B | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1039889497, COSV51661261, COSV51661783; called by mutect2, varscan2
- CARMIL1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV61518971; called by muse, mutect2, varscan2
- CATSPERG | c.3114-1G>A p.X1038_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | catalogued as COSV53049570; called by muse, mutect2, varscan2
- CC2D2B | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60358180; called by muse, mutect2, varscan2
- CCDC127 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs753859156, COSV99371768; called by mutect2, varscan2
- CCDC178 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV55773032; called by mutect2, varscan2
- CCDC28A | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.903); catalogued as rs1187166145, COSV60425221; called by muse, mutect2, varscan2
- CCHCR1 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 42/457 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV52535830; called by muse, mutect2
- CCN2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959044702, COSV63466776; called by muse, mutect2, varscan2
- CCN4 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV51532694; called by muse, mutect2, varscan2
- CCZ1B | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100367706, COSV57438014; called by muse, mutect2
- CD177 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1296994188; called by muse, mutect2
- CDH11 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51765459; called by muse, mutect2, varscan2
- CDH11 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51765470; called by muse, mutect2
- CDH16 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.469); catalogued as COSV55337223; called by muse, mutect2, varscan2
- CDH4 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as rs147810745, COSV64643575; called by muse, mutect2
- CDKN2AIPNL | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV67655214; called by muse, mutect2, varscan2
- CELSR1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53092462; called by muse, mutect2, varscan2
- CENPB | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.781); catalogued as COSV60147371; called by muse, mutect2
- CEP126 | c.600G>C p.M200I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV54826527; called by muse, mutect2, varscan2
- CEP170 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779419108, COSV60510255; called by muse, mutect2, varscan2
- CEP68 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as rs528823795, COSV53124577; called by muse, mutect2, varscan2
- CFAP100 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV61503413; called by muse, mutect2, varscan2
- CFAP43 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV53378649, COSV53379062; called by muse, mutect2, varscan2
- CFAP44 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99870104; called by muse, mutect2
- CFAP65 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.973); catalogued as COSV55390673, COSV55392340; called by muse, mutect2, varscan2
- CHD2 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1318947427, COSV59120750; called by muse, mutect2
- CHD2 | c.2809C>T p.H937Y | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67706954; called by muse, mutect2, varscan2
- CHD4 | c.4121C>T p.P1374L (on ENST00000357008 / NM_001363606.2; = p.P1387L on NM_001273.5) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58903493; called by muse, mutect2, varscan2
- CIT | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55860934; called by muse, mutect2
- CLASP2 | c.3955G>A p.E1319K (on ENST00000359576; = p.E1318K on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV56284932; called by muse, mutect2, varscan2
- CLPTM1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV61612209; called by muse, mutect2, varscan2
- CNTLN | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1486028560, COSV52082185; called by muse, mutect2, varscan2
- COG4 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.161); catalogued as COSV55371864; called by muse, mutect2, varscan2
- COL14A1 | c.5326C>T p.Q1776* | Nonsense Mutation (SNP) | VAF 28/306 reads (9%) | catalogued as rs757806345; called by muse, mutect2
- COL18A1 | c.2482G>A p.D828N (on ENST00000359759 / NM_130444.3; = p.D593N on NM_030582.4) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV62702829; called by muse, mutect2
- COL4A2 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV64629455; called by muse, mutect2
- COL8A2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57442166, COSV57443265; called by muse, mutect2, varscan2
- COLQ | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs764737302, COSV67525083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPB1 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51448928; called by muse, mutect2, varscan2
- COQ10A | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57524469; called by muse, mutect2, varscan2
- CORO6 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV61471166; called by muse, mutect2, varscan2
- CPA2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV55979909; called by muse, mutect2, varscan2
- CPNE1 | c.252G>T p.K84N (on ENST00000352393; = p.K89N on NM_003915.5) | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV58292534; called by muse, mutect2, varscan2
- CR1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as rs534091932, COSV65456666, COSV65459135, COSV65460002; called by muse, mutect2, varscan2
- CRACR2A | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52914078, COSV99068793; called by muse, mutect2, varscan2
- CREB3L3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs143652660; called by muse, mutect2, varscan2
- CRIM1 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV54866091; called by muse, mutect2, varscan2
- CSF3R | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV58965016, COSV58968050; called by muse, mutect2, varscan2
- CSPG5 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53130294; called by muse, mutect2, varscan2
- CYP21A2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM101302, COSV64479423; called by muse, mutect2, varscan2
- CYTH4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757325443, COSV50632594; called by mutect2, varscan2
- DBH | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55041380; called by muse, mutect2, varscan2
- DBI | c.31G>A p.E11K (on ENST00000355857 / NM_001079862.3; = p.E28K on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV58347115; called by muse, mutect2, varscan2
- DCUN1D4 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100584653, COSV58123358; called by muse, mutect2, varscan2
- DCX | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV57570915, COSV57575700; called by muse, mutect2, varscan2
- DECR1 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV55166456, COSV55167083, COSV55170605; called by muse, mutect2
- DFFA | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.037); catalogued as COSV65477075, COSV65477700; called by muse, mutect2, varscan2
- DHRS1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as rs749980818; called by muse, mutect2, varscan2
- DIDO1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV56625507; called by muse, mutect2
- DLGAP5 | c.2142G>C p.L714F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV55963649, COSV55964533; called by muse, mutect2
- DMBX1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63602163; called by muse, mutect2, varscan2
- DMRTC2 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV54187068; called by muse, mutect2, varscan2
- DNAAF2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53570240; called by muse, mutect2, varscan2
- DNAH10 | c.11710C>T p.R3904W (on ENST00000409039; = p.R3843W on NM_207437.3) | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1405250598, COSV68995429, COSV68997180; called by muse, mutect2, varscan2
- DNAH17 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.988); catalogued as COSV67756654; called by muse, mutect2, varscan2
- DOCK4 | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV70238383; called by muse, mutect2, varscan2
- DOCK7 | c.3173C>T p.S1058L (on ENST00000635253 / NM_001367561.1; = p.S1027L on NM_033407.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV52022556; called by muse, mutect2
- DOP1A | c.2683G>C p.E895Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52711895; called by muse, mutect2, varscan2
- DOP1B | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV67692956; called by muse, mutect2, varscan2
- DPP10 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV59683936, COSV59716584; called by muse, mutect2, varscan2
- DPY19L2 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100193579; called by mutect2, varscan2
- DROSHA | c.1161C>G p.I387M | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV60773704; called by muse, mutect2
- DSCAM | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV68029012; called by muse, mutect2, varscan2
- DSPP | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV56811554; called by muse, mutect2, varscan2
- DST | c.10941G>C p.E3647D (on ENST00000361203 / NM_001374722.1; = p.E1235D on NM_015548.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV55020945; called by muse, mutect2, varscan2
- DYRK3 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65605844, COSV65606542; called by muse, varscan2
- DYRK3 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65606551; called by muse, varscan2
- E2F5 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV56275177, COSV56276561; called by muse, mutect2
- ECM1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV60871938; called by muse, mutect2
- EDEM2 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65713149; called by muse, mutect2
- EEF2KMT | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs764625367, COSV69863494; called by muse, mutect2, varscan2
- EHD2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs772336133, COSV54409147; called by muse, mutect2, varscan2
- EHMT2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV64996396; called by muse, mutect2, varscan2
- EIF3K | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 14/163 reads (9%) | catalogued as COSV50264268; called by muse, mutect2
- ELOA | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV69310536; called by muse, mutect2
- EMILIN1 | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53155294; called by muse, mutect2, varscan2
- EN1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.043); catalogued as COSV54631622; called by muse, mutect2, varscan2
- ENTPD7 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.493); catalogued as rs200840103; called by muse, mutect2, varscan2
- EP300 | c.3817G>A p.D1273N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV99608887; called by muse, mutect2
- EPG5 | c.5095G>C p.E1699Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56351140; called by muse, mutect2, varscan2
- EPHB1 | c.1317C>G p.I439M | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs774730651, COSV67663343; called by muse, mutect2, varscan2
- EPHB4 | c.2472G>A p.M824I | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62269309; called by muse, mutect2, varscan2
- ERCC6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV63391185; called by muse, mutect2, varscan2
- ESRRA | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV50007940; called by muse, mutect2, varscan2
- ETFB | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV58536325; called by muse, mutect2, varscan2
- F5 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV63125097; called by muse, mutect2
- FAM160B2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV57158950; called by muse, mutect2, varscan2
- FAM193A | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as COSV61195304; called by muse, mutect2, varscan2
- FAM50A | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as COSV50131588; called by muse, mutect2, varscan2
- FAM50B | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV66654858; called by muse, mutect2, varscan2
- FAM8A1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV52581777; called by muse, mutect2, varscan2
- FAN1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV62950993; called by mutect2, varscan2
- FANCG | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.282); catalogued as COSV62720982; called by muse, mutect2, varscan2
- FANCG | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV62720984; called by muse, mutect2, varscan2
- FBXL2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV52139678; called by muse, mutect2, varscan2
- FBXO30 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52791516; called by muse, mutect2, varscan2
- FCHO1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV53183096; called by muse, mutect2, varscan2
- FCRLA | c.703G>A p.D235N (on ENST00000367959; = p.D212N on NM_032738.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.673); catalogued as COSV52685567; called by muse, mutect2
- FDXR | c.1233G>A p.M411I (on ENST00000293195 / NM_024417.5; = p.M417I on NM_004110.6) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1479952555, COSV53113980; called by muse, mutect2
- FES | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs756990184, COSV60998852; called by muse, mutect2, varscan2
- FGF1 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61803921; called by muse, mutect2, varscan2
- FGR | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as COSV64969660; called by muse, mutect2, varscan2
- FIGN | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV60768024; called by muse, mutect2
- FITM1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs147303563, COSV52824538; called by muse, mutect2, varscan2
- FLG | c.7375C>G p.Q2459E | Missense Mutation (SNP) | VAF 120/1087 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV64243097; called by muse, mutect2, varscan2
- FLG2 | c.5753G>A p.R1918K | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as COSV66169456; called by muse, mutect2
- FLG2 | c.4813C>G p.Q1605E | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV66169461; called by muse, mutect2, varscan2
- FOXQ1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57258702, COSV99723361; called by muse, mutect2
- FREM2 | c.7417C>T p.Q2473* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV54837127; called by muse, mutect2, varscan2
- FRMPD1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV66700751; called by muse, mutect2
- FSCN1 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.937); catalogued as COSV61017827; called by muse, mutect2
- FUBP1 | c.120G>A p.Q40= | Splice Region (SNP) | VAF 55/538 reads (10%) | catalogued as COSV53932508; called by muse, mutect2, varscan2
- FZD7 | c.1527G>C p.K509N | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV53810028; called by muse, mutect2, varscan2
- GABRP | c.456C>G p.L152= | Splice Region (SNP) | VAF 9/104 reads (9%) | catalogued as COSV54663473; called by muse, mutect2, varscan2
- GALM | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as rs539849334, COSV55372372; called by muse, mutect2
- GALNTL6 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV71829113; called by muse, mutect2
- GAS2L1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53330740, COSV53330801; called by muse, mutect2, varscan2
- GATA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as COSV64962141, COSV64963008; called by muse, varscan2
- GATA1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1557020191, COSV64962478; called by muse, mutect2, varscan2
- GATA1 | c.516C>A p.F172L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV64962483; called by muse, varscan2
- GATA1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV64962490; called by muse, varscan2
- GATB | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV56131054; called by muse, mutect2, varscan2
- GCDH | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs375357230, CM105713, CM131394; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GCN1 | c.3677C>G p.S1226C | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV56109459; called by muse, varscan2
- GIGYF2 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1265893036, COSV65250511; called by muse, mutect2
- GIMAP5 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.282); catalogued as rs373837681; called by muse, mutect2
- GINS1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs534317337, COSV52465649; called by muse, mutect2, varscan2
- GLI1 | c.3116C>T p.S1039F | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57363477; called by muse, mutect2, varscan2
- GNAS | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV58331730; called by muse, mutect2, varscan2
- GON4L | c.1585G>C p.D529H | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55195730; called by muse, mutect2
- GPALPP1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV62705994; called by muse, mutect2, varscan2
- GPATCH4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV58040373; called by muse, mutect2, varscan2
- GPC4 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.304); catalogued as COSV63698298; called by muse, mutect2, varscan2
- GPR137C | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55985182; called by muse, mutect2, varscan2
- GPR156 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs183114346, COSV59940595; called by muse, mutect2, varscan2
- GPR52 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52302069; called by muse, mutect2, varscan2
- GPR89B | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58501854; called by muse, mutect2
- GPSM1 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.428); catalogued as COSV52517748; called by muse, mutect2, varscan2
- GRIK3 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66135497; called by muse, mutect2
- GRINA | c.471C>G p.I157M | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57592889; called by muse, mutect2
- GTF3C3 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55832703; called by muse, mutect2, varscan2
- GUCY2D | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV54696729; called by muse, mutect2, varscan2
- H1-7 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs776766561, COSV58602336; called by muse, mutect2, varscan2
- H2AC20 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58611535, COSV58612306; called by muse, mutect2, varscan2
- HCK | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as COSV52943652; called by muse, mutect2
- HDAC2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV64038489; called by muse, mutect2, varscan2
- HELB | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56074170; called by muse, mutect2, varscan2
- HERC6 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs368219425; called by muse, mutect2, varscan2
- HERPUD2 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV60945630, COSV60946088; called by muse, mutect2, varscan2
- HES1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as rs375649870; called by muse, mutect2
- HIPK1 | c.3310C>T p.H1104Y (on ENST00000369558 / NM_001369806.1; = p.H710Y on NM_181358.2) | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV61248604; called by muse, mutect2, varscan2
- HLCS | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV60794597; called by muse, mutect2, varscan2
- HLTF | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59501480, COSV59502031; called by muse, mutect2, varscan2
- HMCN1 | c.7826G>A p.W2609* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs1330531710, COSV54951393; called by muse, mutect2, varscan2
- HNRNPH2 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV54509590; called by muse, mutect2, varscan2
- HSP90AA1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as COSV99355280; called by muse, varscan2
- HTR6 | c.730C>A p.R244S | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.011); catalogued as rs61751019, COSV53873691; called by muse, mutect2, varscan2
- HYDIN | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758283759, COSV55488240; called by mutect2, varscan2
- IFIT2 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV51079340; called by muse, mutect2
- IFNA4 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV70179974, COSV70180048; called by muse, mutect2
- IGF2R | c.2879G>C p.G960A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV63629846; called by muse, mutect2, varscan2
- IGLV2-14 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs776374137; called by muse, mutect2, varscan2
- IGLV3-10 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs531483201; called by muse, mutect2, varscan2
- IL10RB | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51616052, COSV99270245; called by muse, mutect2, varscan2
- INO80 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62739002; called by muse, mutect2, varscan2
- IP6K2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53661875; called by muse, varscan2
- IREB2 | c.2816C>T p.S939L | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as rs1231261203, COSV51921666; called by muse, mutect2, varscan2
- IRX5 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209295297, COSV58059162; called by muse, mutect2, varscan2
- ITGA3 | c.2140-1G>A p.X714_splice | Splice Site (SNP) | VAF 16/248 reads (6%) | catalogued as COSV50316409; called by muse, mutect2
- ITGA5 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as COSV53218507; called by muse, mutect2, varscan2
- ITGAM | c.1639G>A p.E547K (on ENST00000648685 / NM_001145808.2; = p.E546K on NM_000632.4) | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV54938254; called by muse, mutect2, varscan2
- JADE3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV54467365; called by muse, mutect2, varscan2
- JAK1 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV53808062; called by muse, mutect2
- JARID2 | c.2997G>C p.R999S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59191098; called by muse, mutect2, varscan2
- JHY | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV57076256; called by muse, mutect2
- JPH1 | c.482C>G p.T161S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV60611923; called by muse, mutect2
- JUND | c.776C>G p.S259W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53254724; called by muse, mutect2, varscan2
- KALRN | c.3976G>C p.E1326Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53767985; called by muse, mutect2
- KARS1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55613540; called by muse, mutect2, varscan2
- KAT14 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV66608062; called by muse, mutect2
- KAT7 | c.666G>A p.V222= | Splice Region (SNP) | VAF 8/73 reads (11%) | catalogued as rs1386308864, COSV52015046; called by muse, mutect2, varscan2
- KCNN3 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV55219044; called by muse, mutect2
- KCNQ5 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV59664704; called by muse, varscan2
- KCNS2 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV54638938, COSV54639631; called by muse, mutect2
- KDM2A | c.3052C>G p.Q1018E | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58190172; called by muse, mutect2, varscan2
- KHDRBS1 | c.822G>C p.L274F | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56982359; called by muse, mutect2, varscan2
- KIAA0319L | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57846728; called by muse, mutect2, varscan2
- KLB | c.2402C>G p.S801W | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV57302391; called by muse, mutect2, varscan2
- KLHL9 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536145296, COSV62921856; called by muse, mutect2, varscan2
- KMT5B | c.2574G>C p.L858F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58564803; called by muse, mutect2
- KMT5B | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58567068; called by muse, varscan2
- KPNB1 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51597733; called by muse, mutect2, varscan2
- KRT15 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54179942; called by muse, mutect2
- KRT26 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV56970647, COSV56972141; called by muse, mutect2, varscan2
- KRT6A | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs759642583, COSV58105743; called by muse, mutect2, varscan2
- KRTCAP3 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51993915; called by muse, mutect2, varscan2
- LAMA3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV58071003, COSV58074279; called by muse, mutect2, varscan2
- LAMA4 | c.1915G>A p.E639K (on ENST00000230538 / NM_001105206.3; = p.E632K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV57898871; called by muse, mutect2, varscan2
- LEO1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV55176134; called by muse, mutect2, varscan2
- LGALS4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs199814280, COSV57043675; called by muse, mutect2, varscan2
- LGI4 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.387); catalogued as COSV59534018; called by muse, mutect2, varscan2
- LIPG | c.618G>C p.K206N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV54296715; called by muse, mutect2, varscan2
- LMTK2 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV51997674; called by muse, mutect2, varscan2
- LPP | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV57096035; called by muse, mutect2, varscan2
- LRPAP1 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56346476, COSV99578892; called by muse, mutect2, varscan2
- LRRC28 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs754810054, COSV57338983; called by muse, mutect2, varscan2
- LRRC46 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51620218; called by muse, mutect2
- LSAMP | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.166); catalogued as COSV61286231, COSV61287114; called by muse, mutect2, varscan2
- LTBP2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV56209582; called by muse, mutect2
- LYN | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV72923544, COSV72923725; called by muse, mutect2, varscan2
- LYZL2 | c.395G>A p.G132E (on ENST00000375318; = p.G86E on NM_183058.3) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs866625667, COSV100940513, COSV64684507; called by muse, mutect2, varscan2
- MAD2L1 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV56637063; called by muse, varscan2
- MAGI3 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56837884; called by muse, mutect2
- MAP1B | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.714); catalogued as COSV57100749; called by muse, mutect2
- MARCHF10 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60888113; called by muse, mutect2, varscan2
- MAS1L | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as rs773874477; called by muse, mutect2, varscan2
- MATN4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | PolyPhen possibly damaging (0.798); catalogued as COSV59214032; called by muse, mutect2
- MATR3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV63076794; called by muse, mutect2, varscan2
- MBD1 | c.1633G>C p.E545Q (on ENST00000269468 / NM_001323950.1; = p.E443Q on NM_002384.2) | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54002791; called by muse, mutect2, varscan2
- MBOAT7 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV55476223; called by muse, mutect2
- MCM8 | c.755C>G p.P252R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54515045; called by muse, mutect2
- MCTP2 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV63294526; called by muse, mutect2, varscan2
- MED25 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV57205337; called by mutect2, varscan2
- METTL21C | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57432888; called by muse, mutect2, varscan2
- MGA | c.8683G>A p.D2895N (on ENST00000219905 / NM_001164273.1; = p.D2686N on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV54956255; called by muse, mutect2, varscan2
- MID2 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as COSV53310902; called by muse, mutect2, varscan2
- MKRN3 | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV58810331; called by muse, mutect2
- MLPH | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs555987643, COSV52821297; called by muse, mutect2, varscan2
- MMP20 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52775715, COSV52776223; called by muse, mutect2
- MOB1A | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68517554; called by muse, mutect2
- MPHOSPH9 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV100186822, COSV56620802; called by muse, mutect2
- MPP3 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs373244637; called by muse, mutect2, varscan2
- MPZ | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | catalogued as CM013410; called by muse, mutect2, varscan2
- MROH7 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV59873372; called by muse, mutect2
- MROH7 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV59867926; called by muse, mutect2, varscan2
- MS4A1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV61942241; called by muse, mutect2, varscan2
- MTMR12 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53785198, COSV99373986; called by muse, mutect2, varscan2
- MUC16 | c.25322C>A p.P8441H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV67473194; called by muse, mutect2, varscan2
- MUC5AC | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); catalogued as COSV62254255; called by muse, mutect2, varscan2
- MYBPC1 | c.2167C>T p.L723F (on ENST00000550270 / NM_206820.2; = p.L748F on NM_002465.4) | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.836); catalogued as COSV62253831; called by muse, mutect2, varscan2
- MYH2 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55440561, COSV55447305; called by muse, mutect2
- MYO16 | c.1411C>G p.P471A | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774060871, COSV51785944, COSV51799641; called by muse, mutect2, varscan2
- N6AMT1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1198190472, COSV58134755; called by muse, varscan2
- NAGK | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs1239954045, COSV54903143; called by muse, mutect2, varscan2
- NAV3 | c.3317C>T p.S1106L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as COSV57086643; called by muse, mutect2, varscan2
- NBEAL1 | c.7927C>G p.L2643V | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68916247; called by muse, mutect2, varscan2
- NBN | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV55378415; called by muse, mutect2, varscan2
- NCOR1 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV51979191, COSV99063183; called by muse, varscan2
- NDUFS4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57019637; called by muse, mutect2, varscan2
- NEB | c.18624G>C p.Q6208H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51425919; called by muse, mutect2, varscan2
- NEK10 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV100411186, COSV58284771; called by muse, mutect2, varscan2
- NFKBIE | c.1411G>A p.E471K (on ENST00000275015; = p.E332K on NM_004556.3) | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51489545; called by muse, mutect2, varscan2
- NGLY1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54987318; called by muse, mutect2
- NHS | c.4289C>T p.S1430F | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66276998; called by muse, mutect2, varscan2
- NID1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778187483, COSV51620689; called by muse, mutect2, varscan2
- NLRP11 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64087819, COSV64088951; called by muse, mutect2
- NLRP4 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs774809765, COSV56715845; called by muse, mutect2
- NMT2 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65381788; called by muse, mutect2, varscan2
- NOA1 | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV51737505; called by muse, mutect2, varscan2
- NOXRED1 | c.852G>C p.L284F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53627619, COSV53627972; called by muse, mutect2
- NPFF | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57199850; called by muse, mutect2, varscan2
- NT5C1B | c.1771G>A p.E591K (on ENST00000359846 / NM_001199086.2; = p.E531K on NM_033253.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as COSV58396554; called by muse, mutect2, varscan2
- NTRK1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62326216; called by muse, mutect2, varscan2
- NUP62 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61311277, COSV61312423; called by muse, mutect2, varscan2
- NXF1 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53674492; called by muse, mutect2, varscan2
- NXPE3 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56290362; called by muse, mutect2
- OIP5 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs944057665, COSV52971615; called by muse, mutect2, varscan2
- OR10H3 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59944955; called by muse, mutect2
- OTOF | c.2438G>A p.R813Q (on ENST00000272371 / NM_194248.3; = p.R66Q on NM_004802.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as rs767282723, COSV55503544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTULINL | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57034907; called by muse, mutect2
- OTX1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV56995044; called by muse, mutect2, varscan2
- OXLD1 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61303444; called by muse, mutect2
- P2RX3 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV54443126; called by muse, varscan2
- P4HTM | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs751813548, COSV59087591; called by muse, mutect2, varscan2
- PAF1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV55394609; called by muse, varscan2
- PAF1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV55394632; called by muse, varscan2
- PARP1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV64689604; called by muse, mutect2, varscan2
- PARP10 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV57298272; called by muse, mutect2, varscan2
- PARP4 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV67962542; called by muse, mutect2
- PCDHGA4 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53966739; called by muse, mutect2, varscan2
- PCDHGB3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV53950970; called by muse, mutect2, varscan2
- PCF11 | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as rs866354704; called by muse, mutect2, varscan2
- PCMTD2 | c.184C>G p.H62D | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55060393, COSV55060824; called by muse, mutect2, varscan2
- PCNX4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58305119; called by muse, mutect2, varscan2
- PCYOX1 | c.111C>T p.I37= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52476777; called by muse, mutect2, varscan2
- PDCD7 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52600653; called by muse, mutect2, varscan2
- PDE4A | c.2323G>A p.E775K (on ENST00000380702 / NM_001111307.2; = p.E536K on NM_006202.3) | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53357353; called by muse, mutect2
- PDZD8 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV57823670, COSV57826263; called by muse, mutect2, varscan2
- PEX11B | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs782789478, COSV65197798; called by muse, mutect2, varscan2
- PFKFB1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | PolyPhen benign (0.092); catalogued as COSV66628645; called by muse, mutect2, varscan2
- PGM5 | c.1107T>A p.N369K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67164102; called by muse, mutect2, varscan2
- PHF11 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.534); catalogued as COSV62896633; called by muse, mutect2, varscan2
- PHF20 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.14); catalogued as COSV59186680, COSV59186687; called by muse, mutect2, varscan2
- PHF20L1 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55191955, COSV55194048; called by muse, mutect2, varscan2
- PHLDA3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66210854; called by muse, mutect2, varscan2
- PHLDB2 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV101208426, COSV67312493; called by muse, mutect2, varscan2
- PIGG | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV56318855; called by muse, mutect2
- PIGT | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54126875; called by muse, mutect2, varscan2
- PKD2L1 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58395859, COSV58396557; called by muse, mutect2, varscan2
- PLA2R1 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs1274396853, COSV51780639; called by muse, mutect2, varscan2
- PLA2R1 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51780646; called by muse, mutect2, varscan2
- PLAUR | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.957); catalogued as rs751894490, COSV55390239; called by muse, mutect2, varscan2
- PLEC | c.9215C>A p.A3072E (on ENST00000322810 / NM_201380.4; = p.A2962E on NM_000445.5) | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59648212; called by muse, mutect2, varscan2
- PLEC | c.6181G>A p.E2061K (on ENST00000322810 / NM_201380.4; = p.E1951K on NM_000445.5) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59648249; called by muse, mutect2, varscan2
- PLEKHM2 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV65395875; called by muse, mutect2, varscan2
- PLK4 | c.1763G>C p.R588T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV54637865; called by muse, mutect2, varscan2
- PMP22 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV56602485; called by muse, mutect2
- POLR1A | c.5016G>A p.M1672I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV55694260; called by muse, mutect2, varscan2
- POP1 | c.2984C>T p.S995F | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.116); catalogued as rs372595102; called by muse, mutect2, varscan2
- POU2F1 | c.1061-1G>A p.X354_splice (on ENST00000541643 / NM_001365848.1; = p.X377_splice on NM_002697.4) | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV54818662; called by muse, mutect2
- PPFIA3 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs759215269, COSV53256908; called by mutect2, varscan2
- PPL | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52169025; called by muse, mutect2, varscan2
- PPL | c.2361C>G p.I787M | Missense Mutation (SNP) | VAF 70/669 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV62047944, COSV62050475; called by muse, mutect2, varscan2
- PPP1R32 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV58545217; called by muse, mutect2, varscan2
- PRKDC | c.6172G>A p.D2058N | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV58055177; called by muse, mutect2, varscan2
- PRKG2 | c.1251G>A p.A417= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as rs112801782; called by muse, mutect2, varscan2
- PRUNE2 | c.5134G>A p.D1712N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65042756; called by muse, mutect2, varscan2
- PSMC2 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53007829; called by muse, mutect2, varscan2
- PTBP2 | c.1543C>G p.Q515E (on ENST00000426398 / NM_001300986.2; = p.Q506E on NM_021190.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64624885; called by muse, mutect2
- PTCH2 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV64711491; called by muse, mutect2, varscan2
- PTPN13 | c.7090G>C p.E2364Q (on ENST00000411767 / NM_080683.3; = p.E2345Q on NM_006264.3) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57409474; called by muse, mutect2, varscan2
- PTPN4 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55303097; called by muse, mutect2, varscan2
- PTPRK | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as COSV63887903; called by muse, mutect2, varscan2
- PYGL | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53586530; called by muse, mutect2, varscan2
- RAB24 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.277); catalogued as rs1486733376, COSV57463451; called by muse, mutect2, varscan2
- RAB3D | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV55792111; called by muse, mutect2, varscan2
- RAD23A | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57128053; called by muse, mutect2
- RARG | c.1019-1G>A p.X340_splice | Splice Site (SNP) | VAF 11/99 reads (11%) | catalogued as COSV58433264; called by muse, mutect2
- RASGRP2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV62449797; called by muse, mutect2, varscan2
- RBMS1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs754144868, COSV62353933; called by muse, mutect2, varscan2
- RBPJ | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV60752524; called by muse, mutect2, varscan2
- RC3H2 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100605631; called by muse, mutect2, varscan2
- RC3H2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100106699; called by muse, mutect2
- RCSD1 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 58/536 reads (11%) | catalogued as COSV63259341; called by muse, mutect2, varscan2
- REL | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV54365044; called by muse, mutect2
- RFX6 | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60586088, COSV60586503; called by muse, mutect2
- RGS14 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.557); catalogued as COSV68771391; called by mutect2, varscan2
- RGS22 | c.2669G>C p.R890T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100693575; called by muse, mutect2
- RIMKLB | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV55237820; called by muse, mutect2, varscan2
- RNF39 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54993628; called by muse, mutect2
- RNF8 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as rs1173461883, COSV57721586; called by muse, mutect2, varscan2
- RNFT1 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV59869949; called by muse, mutect2, varscan2
- RNPEP | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241755; called by muse, mutect2
- RPRD1B | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65033202; called by muse, mutect2, varscan2
- RPS18 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as COSV65851717; called by muse, mutect2, varscan2
- RRP1B | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61479274; called by muse, mutect2
- RSC1A1 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV60780045; called by muse, varscan2
- RSC1A1 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60780051; called by muse, mutect2
- RSC1A1 | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 63/345 reads (18%) | catalogued as rs947684905, COSV100197667; called by muse, mutect2, varscan2
- RSPH14 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53269459; called by muse, mutect2
- RTEL1 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV58895986; called by muse, mutect2
- RTN3 | c.701C>T p.S234L (on ENST00000377819 / NM_001265589.2; = p.S215L on NM_201428.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as rs755612658, COSV58029493; called by muse, varscan2
- RUBCNL | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV59786115; called by muse, mutect2, varscan2
- RXFP3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.143); catalogued as rs761783066, COSV100347414, COSV57506243; called by muse, mutect2
- SAP18 | c.338G>C p.R113T (on ENST00000607003; = p.R132T on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV66822798, COSV66822847; called by muse, mutect2, varscan2
- SAPCD1 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV65173497; called by muse, mutect2
- SART3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); catalogued as rs578149175, COSV57207983; called by muse, mutect2, varscan2
- SBF1 | c.4470C>G p.F1490L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV62368112, COSV62370546; called by muse, mutect2, varscan2
- SBSPON | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV52076858; called by muse, mutect2
- SCAF4 | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV54588388; called by muse, mutect2, varscan2
- SCFD1 | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV61724546; called by muse, mutect2, varscan2
- SCN8A | c.3576C>A p.F1192L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV61983925; called by muse, mutect2, varscan2
- SCRN2 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.87); catalogued as COSV51636174; called by muse, mutect2, varscan2
- SCUBE2 | c.2467G>A p.D823N (on ENST00000649792 / NM_001367977.2; = p.D766N on NM_020974.3) | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745468428, COSV58543609; called by muse, mutect2, varscan2
- SCUBE3 | c.2931C>A p.F977L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51457761; called by muse, varscan2
- SDAD1 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 18/155 reads (12%) | catalogued as COSV62402426; called by muse, mutect2, varscan2
- SEC16B | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV57626932; called by muse, mutect2, varscan2
- SEC24A | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs960780838, COSV59747823; called by muse, mutect2, varscan2
- SEL1L2 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53153622; called by muse, mutect2, varscan2
- SEMA3F | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 27/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs749081279, COSV50030659; called by muse, mutect2
- SEMA5B | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as COSV52100579; called by muse, mutect2
- SEPTIN4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV57896864; called by muse, mutect2, varscan2
- SF3A3 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV65956028, COSV65956489; called by muse, mutect2
- SF3B1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV59207677; called by muse, mutect2, varscan2
- SGSM3 | c.366+1G>A p.X122_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as rs763690735, COSV50652877; called by mutect2, varscan2
- SH2D1B | c.364-1G>T p.X122_splice | Splice Site (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100854829; called by muse, mutect2, varscan2
- SH3BP5L | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs757361561, COSV63539416, COSV63539662; called by mutect2, varscan2
- SH3TC2 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV60464380; called by muse, mutect2, varscan2
- SHOC1 | c.3619C>G p.L1207V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV59503028; called by muse, mutect2, varscan2
- SIPA1 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58015061; called by muse, mutect2, varscan2
- SIPA1L2 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53392278; called by muse, mutect2, varscan2
- SIPA1L3 | c.5082G>T p.E1694D | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.743); catalogued as COSV55916551; called by muse, mutect2
- SLC12A4 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs372093952; called by muse, mutect2
- SLC12A5 | c.1298C>T p.S433L (on ENST00000454036 / NM_001134771.2; = p.S410L on NM_020708.5) | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV54795298; called by muse, mutect2
- SLC12A5 | c.2704C>G p.L902V (on ENST00000454036 / NM_001134771.2; = p.L879V on NM_020708.5) | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV54795323; called by muse, mutect2
- SLC22A10 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441138125, COSV100235972, COSV60421190, COSV60421696; called by muse, mutect2, varscan2
- SLC30A7 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as COSV63017848; called by muse, mutect2, varscan2
- SLC32A1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs748975423, COSV54146491; called by muse, mutect2
- SLC45A3 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV65655072; called by muse, mutect2, varscan2
- SLC6A17 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.566); catalogued as COSV58993988; called by muse, mutect2, varscan2
- SLC6A6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV62650419; called by muse, mutect2, varscan2
- SLC6A9 | c.727C>T p.R243W (on ENST00000360584 / NM_201649.4; = p.R189W on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs774340135, COSV62211007; called by muse, mutect2, varscan2
- SLCO4A1 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV53891636; called by muse, mutect2, varscan2
- SLFN5 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55481618; called by muse, mutect2
- SMARCD1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV67412236; called by muse, mutect2, varscan2
- SNRPC | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.885); catalogued as COSV55075703, COSV99765140; called by muse, mutect2
- SNX15 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57247308; called by muse, mutect2, varscan2
- SNX18 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57987786; called by muse, mutect2
- SNX25 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV53015475; called by muse, mutect2, varscan2
- SNX29 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60062024; called by muse, mutect2, varscan2
- SOX12 | c.257A>T p.K86M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258934; called by muse, mutect2
- SOX18 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV61110497; called by muse, mutect2
- SPAG4 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV65330633; called by muse, mutect2
- SPATA9 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57224460; called by muse, mutect2, varscan2
- SPATC1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs781835810, COSV66299123; called by muse, mutect2, varscan2
- SPINK2 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV50534320; called by muse, mutect2, varscan2
- SPTA1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs367886335; called by muse, mutect2, varscan2
- SRCAP | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52674777; called by muse, varscan2
- SRRM2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57074778; called by muse, mutect2, varscan2
- SRRM2 | c.4222G>C p.D1408H | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV57074824; called by muse, mutect2, varscan2
- SRSF1 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51965393; called by muse, mutect2
- SS18 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV52261812; called by muse, mutect2, varscan2
- STAT3 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52888704; called by muse, mutect2
- STAT6 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55671734; called by muse, mutect2, varscan2
- STK4 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65670493; called by muse, mutect2, varscan2
- STX5 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53673299; called by muse, mutect2
- STXBP6 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60593697; called by muse, mutect2, varscan2
- SULF1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52684275; called by muse, mutect2, varscan2
- SUSD2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64204332; called by muse, mutect2, varscan2
- SYCP2L | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.15); catalogued as COSV51654130; called by muse, mutect2
- SYNE1 | c.14500C>T p.R4834* (on ENST00000367255 / NM_182961.4; = p.R4763* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs766129413, COSV55042757; called by muse, mutect2, varscan2
- SYNPO2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61112596; called by muse, mutect2, varscan2
- TAAR8 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV51586516; called by muse, mutect2, varscan2
- TAF11 | c.506-1G>C p.X169_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99512004; called by muse, mutect2
- TAF1B | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs374536272; called by mutect2, varscan2
- TAF8 | c.590C>G p.T197R | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65896310; called by muse, mutect2, varscan2
- TARBP2 | c.335C>T p.S112F (on ENST00000266987 / NM_134323.2; = p.S91F on NM_004178.4) | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV57199847; called by muse, mutect2
- TAS2R16 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.451); catalogued as rs1362905591, COSV50797360; called by muse, mutect2, varscan2
- TASOR | c.4666C>G p.Q1556E (on ENST00000355628 / NM_001365636.2; = p.Q1180E on NM_015224.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58305151; called by muse, mutect2
- TAX1BP1 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55294110; called by muse, mutect2, varscan2
- TBL1Y | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV60733264; called by muse, mutect2, varscan2
- TBX3 | c.1295C>T p.S432L (on ENST00000257566 / NM_016569.4; = p.S412L on NM_005996.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57472638; called by muse, mutect2, varscan2
- TBXT | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51618573; called by muse, mutect2
- TCTN2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1208320131, COSV57633362; called by muse, mutect2, varscan2
- TEAD4 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV63281427; called by muse, mutect2, varscan2
- TECTA | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50687602, COSV50689301; called by muse, mutect2
- TFEB | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV57825282; called by muse, varscan2
- TG | c.3786G>T p.L1262F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55080422; called by muse, mutect2
- THAP8 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV53078443; called by muse, mutect2, varscan2
- TLE2 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53580697; called by muse, mutect2, varscan2
- TLL2 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as COSV63573174; called by muse, mutect2, varscan2
- TMEM123 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); catalogued as COSV63444147; called by muse, mutect2, varscan2
- TMEM199 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV50228517, COSV50228849; called by muse, mutect2, varscan2
- TMEM266 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391701952, COSV66379815; called by muse, mutect2, varscan2
- TMEM67 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60040811; called by muse, mutect2
- TMX4 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs781395988, COSV55681048; called by muse, mutect2, varscan2
- TNC | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100405903; called by muse, mutect2, varscan2
- TNFRSF8 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV55795552, COSV55797290, COSV55799545; called by muse, varscan2
- TNR | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 33/412 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV54877357; called by muse, mutect2
- TNRC6C | c.4133C>T p.S1378L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56947372; called by muse, mutect2
- TOGARAM1 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1461560324, COSV100753296, COSV61888471; called by muse, mutect2, varscan2
- TOLLIP | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528881976, COSV55136721; called by muse, mutect2, varscan2
- TOM1L1 | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61947992; called by muse, mutect2, varscan2
- TPST2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1185763236, COSV58680315; called by muse, mutect2
- TRAF2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV56038207, COSV99916118; called by muse, mutect2, varscan2
- TRERF1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV61673315; called by muse, mutect2, varscan2
- TRIL | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59867314; called by muse, mutect2, varscan2
- TRIM15 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV100938804, COSV64988985; called by muse, mutect2, varscan2
- TRIM28 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV53400663; called by muse, mutect2
- TRIM38 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62641691; called by muse, mutect2, varscan2
- TRIM47 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54668670; called by muse, mutect2, varscan2
- TRMT13 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs950891502, COSV61583189, COSV99048576; called by muse, mutect2, varscan2
- TSC22D1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71775805; called by muse, mutect2, varscan2
- TSHZ2 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV61588659, COSV61589419; called by muse, mutect2
- TSPYL5 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV59071843; called by muse, mutect2, varscan2
- TTC21B | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV54631644; called by muse, mutect2, varscan2
- TTC30A | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV63101706; called by muse, varscan2
- TTC30A | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63101711; called by muse, varscan2
- TTYH1 | c.1033-1G>A p.X345_splice | Splice Site (SNP) | VAF 28/156 reads (18%) | catalogued as COSV56612600; called by muse, mutect2, varscan2
- TXLNB | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV64444403; called by muse, mutect2, varscan2
- UBOX5 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as COSV53906629; called by muse, mutect2
- UMODL1 | c.3787C>A p.H1263N (on ENST00000408910 / NM_001004416.2; = p.H1391N on NM_173568.3) | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV68570137; called by muse, mutect2, varscan2
- UMPS | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1402190366, COSV51737649; called by muse, mutect2, varscan2
- UNC13B | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs199517826; called by muse, mutect2, varscan2
- UNC79 | c.6685C>T p.Q2229* (on ENST00000393151 / NM_001346218.2; = p.Q2052* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56383871; called by muse, mutect2, varscan2
- URI1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV56350673; called by muse, mutect2, varscan2
- USH2A | c.11479C>T p.Q3827* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | catalogued as COSV56393704; called by muse, mutect2, varscan2
- USP20 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.995); catalogued as rs768323864, COSV59614998; called by muse, mutect2, varscan2
- USP29 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54143727, COSV99518065; called by muse, mutect2
- USP47 | c.796G>A p.E266K (on ENST00000399455 / NM_001372095.1; = p.E178K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60464828; called by mutect2, varscan2
- USP48 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57610564; called by muse, mutect2, varscan2
- USPL1 | c.3206C>T p.S1069L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs774650540, COSV55000418; called by mutect2, varscan2
- UTRN | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV62338011; called by muse, mutect2
- UVSSA | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV66230052; called by muse, mutect2, varscan2
- VCAM1 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs772033172, COSV54119977; called by mutect2, varscan2
- VCPIP1 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60048196; called by muse, mutect2, varscan2
- VLDLR | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775603429, COSV66077667; called by muse, mutect2, varscan2
- VPS11 | c.151C>T p.P51S (on ENST00000620429; = p.P595S on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as COSV56185032; called by muse, mutect2
- VPS13D | c.4576G>A p.E1526K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV50646529; called by muse, mutect2
- VSIR | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs780017291, COSV56470480; called by muse, mutect2, varscan2
- VWCE | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57113056; called by muse, mutect2, varscan2
- WASF3 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs781737859, COSV58967343; called by muse, varscan2
- WBP11 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.585); catalogued as rs775971289, COSV53763329; called by muse, mutect2, varscan2
- WDR54 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV51963994; called by muse, mutect2
- WNT3A | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV52731624; called by muse, mutect2, varscan2
- XKR7 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73813230; called by muse, mutect2
- XKR8 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV65855009; called by muse, mutect2, varscan2
- XPO7 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV53015946; called by muse, mutect2, varscan2
- XPOT | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as COSV60346046; called by muse, mutect2
- XPOT | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1272193653, COSV60346054; called by muse, mutect2, varscan2
- ZBTB7B | c.310G>C p.E104Q (on ENST00000292176; = p.E138Q on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52692915, COSV52693144; called by muse, mutect2
- ZBTB7B | c.916G>C p.D306H (on ENST00000292176; = p.D340H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52693181, COSV99420765; called by muse, mutect2
- ZFAND2A | c.106C>A p.H36N | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57180504; called by muse, mutect2
- ZFP36L2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2
- ZFYVE9 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55095093; called by muse, mutect2, varscan2
- ZNF112 | c.2147C>T p.S716F (on ENST00000337401 / NM_001083335.2; = p.S710F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV61620610; called by muse, mutect2, varscan2
- ZNF160 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV62000008, COSV62001029; called by muse, mutect2
- ZNF165 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV66102615; called by muse, mutect2
- ZNF200 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs773833164, COSV67723954; called by muse, mutect2
- ZNF221 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs999095179, COSV52107828; called by muse, mutect2, varscan2
- ZNF260 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV72951233; called by muse, mutect2, varscan2
- ZNF264 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54042244, COSV99567324; called by muse, mutect2, varscan2
- ZNF292 | c.6511G>C p.E2171Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60540944; called by mutect2, varscan2
- ZNF341 | c.1387C>T p.H463Y (on ENST00000375200 / NM_001282935.1; = p.H456Y on NM_032819.4) | Missense Mutation (SNP) | VAF 56/619 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61007881; called by muse, mutect2
- ZNF347 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV61969191; called by muse, mutect2, varscan2
- ZNF462 | c.6101C>G p.S2034C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52942447; called by muse, mutect2
- ZNF526 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV56630092; called by muse, mutect2
- ZNF529 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV61900856, COSV61901919; called by muse, mutect2, varscan2
- ZNF568 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs753710178, COSV61741444; called by muse, mutect2, varscan2
- ZNF582 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV56732536; called by muse, mutect2
- ZNF600 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV57743168; called by muse, mutect2, varscan2
- ZNF606 | c.1191G>C p.E397D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV58706332; called by muse, mutect2
- ZNF607 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV67697188; called by muse, mutect2, varscan2
- ZNF623 | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101513475, COSV71697222; called by muse, mutect2, varscan2
- ZNF623 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV101513566; called by muse, mutect2
- ZNF684 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65519213; called by muse, mutect2, varscan2
- ZNF791 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.715); catalogued as COSV58481339; called by muse, mutect2, varscan2
- ZNF792 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as rs1568551974; called by muse, mutect2, varscan2
- ZNF808 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs781451094, COSV63120263; called by muse, mutect2, varscan2
- ZSCAN21 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs372435376; called by muse, mutect2, varscan2
- ZZEF1 | c.6658G>A p.D2220N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV101067792; called by muse, mutect2
- ACSS3 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- AKAP6 | c.5787G>C p.E1929D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- APOL2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 38/252 reads (15%) | called by muse, mutect2, varscan2
- ATXN2 | c.1349C>G p.S450* (on ENST00000550104; = p.S290* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- B3GNT9 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- C2orf16 | c.5490_5491dup p.H1831Lfs*62 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- CACNA1D | c.6017C>G p.S2006* (on ENST00000350061 / NM_001128840.3; = p.S2026* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- CAPN3 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- CASC3 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- CASS4 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 32/301 reads (11%) | called by muse, mutect2, varscan2
- CDKN1A | c.330dup p.V111Cfs*18 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- CHD2 | c.3193G>C p.E1065Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- CIAO1 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- CLRN1 | c.260C>T p.P87L (on ENST00000327047 / NM_174878.3; = p.P11L on NM_052995.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- DST | c.4390G>C p.E1464Q (on ENST00000361203 / NM_001374722.1; = p.E1138Q on NM_015548.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2
- EFR3A | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2
- ELOA | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ELOVL7 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- EYA3 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- FAM83C | c.1196C>G p.S399* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- FSTL1 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- GPR88 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- H2AC17 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- HECTD4 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HTR1A | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); called by muse, mutect2
- ICA1 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGSF10 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- IL6 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2
- INO80D | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KDR | c.2026C>T p.Q676* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- KLHL5 | c.2064G>A p.W688* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- LIMA1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- LY75 | c.4691C>G p.S1564* | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- MTTP | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- NFATC2 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- NOD2 | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- NUP153 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- OR5K4 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PALLD | c.1133C>G p.S378* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- PARD3 | c.3437C>G p.S1146* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- PARP1 | c.1301-1G>C p.X434_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- PARP4 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- PPME1 | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- PRKDC | c.11932G>A p.G3978S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- PRRC2B | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- PTBP2 | c.1366C>G p.Q456E (on ENST00000426398 / NM_001300986.2; = p.Q448E on NM_021190.4) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- PTPRK | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- PTPRZ1 | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); called by muse, mutect2
- RAB11FIP4 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- RBP3 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF111 | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- RSC1A1 | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by muse, varscan2
- RTN3 | c.791C>G p.S264* (on ENST00000377819 / NM_001265589.2; = p.S245* on NM_201428.3) | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | called by muse, varscan2
- SLC1A3 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- SLCO1B1 | c.2008T>A p.L670I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- SLITRK5 | c.792T>A p.C264* | Nonsense Mutation (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- SMC5 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- SNX14 | c.994-1G>C p.X332_splice (on ENST00000314673 / NM_001350535.1; = p.X288_splice on NM_020468.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- SPON1 | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); called by muse, varscan2
- TNRC6C | c.2076G>A p.W692* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- TOPORS | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2
- TOR1AIP1 | c.950C>G p.S317* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- TTN | c.17470C>G p.L5824V (on ENST00000591111; = p.L4897V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | PolyPhen possibly damaging (0.6); called by muse, mutect2
- TUBA1A | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBAP2 | c.1253C>A p.S418* | Nonsense Mutation (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- USP29 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- XPO1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2
- XRN2 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZDHHC6 | c.825_835del p.F276Rfs*4 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- ZNF407 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- ZNF530 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- ZNF791 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- ABCC12 | c.180C>T p.L60= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV60914648; called by muse, mutect2, varscan2
- ABCG1 | c.852C>T p.F284= | Silent (SNP) | VAF 53/325 reads (16%) | catalogued as rs373041473, COSV59207485; called by muse, mutect2, varscan2
- ABCG8 | c.1563G>A p.L521= | Silent (SNP) | VAF 16/197 reads (8%) | catalogued as COSV55394011; called by muse, mutect2
- ACACA | c.1083C>T p.V361= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- ACTB | c.24C>A p.L8= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as rs151181948, COSV59319057; called by muse, mutect2, varscan2
- ADAM11 | c.843C>G p.L281= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as COSV52347062; called by muse, mutect2, varscan2
- ADAMTS10 | c.966G>A p.V322= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV54355858; called by muse, mutect2
- ADAMTS16 | c.2448C>T p.F816= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV56976343; called by muse, mutect2, varscan2
- ADCY10 | c.1087C>T p.L363= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV63241501; called by muse, mutect2, varscan2
- ADCY5 | c.3021G>A p.Q1007= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV59199271; called by muse, mutect2, varscan2
- ADGRD1 | c.540G>A p.L180= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1445814810, COSV55448075; called by muse, mutect2, varscan2
- ADGRL2 | c.2616C>T p.F872= (on ENST00000370717 / NM_001366005.1; = p.F859= on NM_012302.4) | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV54657911; called by muse, mutect2
- ADM2 | c.246C>T p.L82= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV53313448, COSV99326872; called by muse, mutect2, varscan2
- AHCYL1 | c.420G>A p.E140= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV63208882; called by muse, mutect2, varscan2
- ALAS2 | c.243G>A p.K81= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV58191445; called by muse, mutect2, varscan2
- ALPP | c.273G>A p.L91= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV67396691; called by muse, mutect2, varscan2
- AMER3 | c.666C>G p.L222= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV58467586; called by muse, mutect2, varscan2
- AMOTL1 | c.1038C>G p.V346= | Silent (SNP) | VAF 36/261 reads (14%) | catalogued as COSV54416402; called by muse, mutect2, varscan2
- ANGPTL2 | c.378G>A p.E126= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1409156536, COSV52224323; called by muse, mutect2, varscan2
- ANKRD27 | c.468C>T p.I156= | Silent (SNP) | VAF 82/400 reads (21%) | catalogued as rs778113626, COSV60132609; called by muse, mutect2, varscan2
- ANKRD55 | c.1074G>A p.Q358= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV61947459; called by muse, mutect2
- AP1B1 | c.1701C>T p.I567= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as rs1176074282, COSV58018766; called by muse, mutect2, varscan2
- APC2 | c.1746G>T p.V582= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as COSV52019421; called by muse, varscan2
- APOBEC3B | c.924C>T p.F308= | Silent (SNP) | VAF 38/230 reads (17%) | catalogued as rs144471703; called by muse, varscan2
- APOL2 | c.381T>A p.S127= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV50772289; called by muse, mutect2, varscan2
- APOL4 | c.507G>A p.L169= (on ENST00000352371 / NM_145660.2; = p.L166= on NM_030643.4) | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- ARMC12 | c.429C>T p.F143= (on ENST00000373866 / NM_001286574.2; = p.F170= on NM_145028.5) | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV55360410; called by muse, mutect2
- ASPH | c.1857G>A p.L619= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1468671867, COSV65245182; called by mutect2, varscan2
- ATG7 | c.1743G>A p.V581= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs1388403885, COSV61613299; called by muse, mutect2, varscan2
- ATIC | c.528G>A p.L176= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV52693683, COSV99377792; called by muse, mutect2, varscan2
- B3GNT2 | c.951G>C p.L317= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV100114132, COSV57344938; called by muse, mutect2, varscan2
- BANK1 | c.2133G>C p.L711= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV59844600; called by muse, mutect2, varscan2
- BIRC6 | c.2160G>A p.L720= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV70200882; called by muse, mutect2, varscan2
- BLOC1S5 | c.306C>T p.L102= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV55241850; called by muse, mutect2
- BOD1 | c.351G>A p.Q117= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs768531548, COSV53632713; called by muse, mutect2, varscan2
- BPIFB3 | c.1430G>A p.*477= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- CACNA2D4 | c.540C>T p.F180= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV54952052; called by muse, mutect2, varscan2
- CACNG5 | c.552C>T p.I184= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV50054841; called by muse, mutect2, varscan2
- CALHM2 | c.615C>G p.L205= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53295452; called by muse, mutect2, varscan2
- CALR | c.978C>T p.I326= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs1350005255, COSV57128048; called by muse, mutect2, varscan2
- CASP4 | c.417C>T p.L139= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV67744515; called by muse, mutect2, varscan2
- CBLC | c.906G>A p.Q302= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV54323331; called by muse, mutect2, varscan2
- CBLN2 | c.609G>A p.E203= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs1343851330, COSV54051523, COSV54051609; called by muse, mutect2
- CCDC50 | c.1281G>A p.E427= (on ENST00000392455 / NM_178335.3; = p.E251= on NM_174908.4) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1209146937; called by muse, mutect2
- CCN1 | c.804G>A p.E268= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV71704372; called by muse, mutect2, varscan2
- CD163L1 | c.3201G>C p.L1067= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV58010820, COSV58017978; called by muse, mutect2, varscan2
- CD37 | c.213C>T p.I71= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs780073603, COSV60544594; called by muse, mutect2, varscan2
- CD53 | c.258C>T p.F86= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as COSV54761768; called by muse, mutect2
- CDA | c.348C>T p.Y116= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1317796542, COSV66751942; called by muse, mutect2
- CEP170B | c.3525G>A p.R1175= (on ENST00000453495; = p.R1104= on NM_015005.3) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV69025057; called by muse, mutect2, varscan2
- CHD6 | c.3558G>A p.G1186= | Silent (SNP) | VAF 17/178 reads (10%) | catalogued as rs1469102206, COSV58558343; called by muse, mutect2, varscan2
- CHKB | c.1074C>A p.I358= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV56417237; called by muse, mutect2, varscan2
- CHMP6 | c.480G>A p.L160= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57327529; called by muse, mutect2, varscan2
- CHRDL2 | c.456C>G p.L152= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55223476; called by muse, mutect2, varscan2
- CIC | c.4254C>A p.S1418= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as COSV50592691; called by muse, mutect2, varscan2
- CLEC1B | c.414G>T p.L138= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100045912, COSV53725732; called by muse, mutect2, varscan2
- CMTR1 | c.924C>T p.F308= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV65090666; called by muse, mutect2
- CNBD2 | c.936G>A p.L312= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV62587146; called by muse, mutect2, varscan2
- COG4 | c.270G>A p.L90= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV60423056, COSV60423326; called by muse, mutect2, varscan2
- COL19A1 | c.3123C>A p.L1041= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV59576135; called by muse, mutect2, varscan2
- COPG1 | c.2196C>G p.V732= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV59114608; called by muse, mutect2, varscan2
- COQ4 | c.217C>T p.L73= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1407886704, COSV55957289, COSV55957718; called by muse, mutect2, varscan2
- CRACD | c.504G>A p.Q168= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs745705035, COSV51723461; called by muse, mutect2, varscan2
- CRKL | c.81G>A p.R27= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV62883500; called by muse, mutect2, varscan2
- CRMP1 | c.1593C>T p.I531= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV61480938; called by muse, mutect2, varscan2
- CYP3A4 | c.837G>A p.Q279= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100316008, COSV60502547; called by muse, mutect2
- DCTN4 | c.633G>A p.Q211= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV69781801, COSV69782409; called by muse, mutect2, varscan2
- DDX3X | c.720G>A p.Q240= (on ENST00000399959; = p.Q241= on NM_001356.5) | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV67863863; called by muse, mutect2, varscan2
- DDX49 | c.726C>T p.F242= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV53230941; called by muse, mutect2, varscan2
- DENR | c.495C>T p.I165= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
246 further variants in this file (0 protein-altering or splice-affecting, 228 silent, 18 other) are not listed here.
